Somatic mutation profile of tumor specimen TCGA-AJ-A8CV-01A (aliquot TCGA-AJ-A8CV-01A-11D-A37N-09) from TCGA case TCGA-AJ-A8CV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 58.4 years (21,336 days).
Specimen TCGA-AJ-A8CV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09814c79-3147-4871-a0c9-4d433ba98729.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A8CV-10A (Blood Derived Normal), aliquot TCGA-AJ-A8CV-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/798aa084-ec0f-4b7f-aa6a-e0f29fe3ccde

The open-access MAF lists 267 somatic variants for this specimen: 206 protein-altering or splice-affecting, 56 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 56, Frame Shift Del 50, Frame Shift Ins 7, Splice Site 6, Nonsense Mutation 5, 3'UTR 4, In Frame Del 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.164+1G>T p.X55_splice | Splice Site (SNP) | VAF 19/41 reads (46%) | catalogued as rs1554893835, CD043800, CS013829, CS132270, CS147226, COSV64291461, COSV64302445, COSV64308544; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.3667G>A p.A1223T (on ENST00000614293; = p.A1193T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1279759803, COSV99688576; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs749943218; called by mutect2, varscan2
- ACVR2A | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV99604891, COSV99605241; called by muse, mutect2, varscan2
- ADAD1 | c.244del p.I82Yfs*6 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs746068816; called by mutect2, varscan2
- ADPRS | c.247A>G p.R83G | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV99255649; called by muse, mutect2, varscan2
- ADTRP | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145096274; called by muse, mutect2, varscan2
- AGK | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs368565785; called by muse, mutect2, varscan2
- AGRN | c.4517C>T p.A1506V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs373657385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP8L | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.024); catalogued as rs565853529, COSV101275894; called by muse, mutect2, varscan2
- AMBRA1 | c.1390A>G p.T464A (on ENST00000458649 / NM_001367468.1; = p.T374A on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100095539; called by muse, mutect2, varscan2
- ANK2 | c.1105C>T p.L369F | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100004571; called by muse, mutect2, varscan2
- ANKZF1 | c.1802A>G p.Q601R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs774305364, COSV99850955; called by muse, mutect2, varscan2
- AOX1 | c.1982A>G p.K661R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV101022259; called by muse, mutect2, varscan2
- ARHGEF7 | c.1984C>T p.R662W (on ENST00000375741 / NM_001113511.2; = p.R484W on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99522239; called by muse, mutect2, varscan2
- ARL2 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748651201, COSV55861697, COSV99880720; called by muse, mutect2, varscan2
- ARPP21 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs140987024; called by muse, mutect2, varscan2
- ATP2C2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99297519; called by mutect2, varscan2
- BCHE | c.1628G>C p.R543P | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100013055; called by muse, mutect2, varscan2
- BCL2L12 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1357117189, COSV99881348; called by muse, mutect2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BDKRB2 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs751331696, COSV100021056; called by muse, mutect2, varscan2
- BDP1 | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV100703631; called by muse, mutect2, varscan2
- BEST3 | c.393C>G p.Y131* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV56995325, COSV99876419; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BRD1 | c.1468del p.A490Pfs*26 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as COSV53458006; called by mutect2, pindel, varscan2
- BSN | c.6028C>T p.R2010* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV56516579; called by muse, mutect2, varscan2
- CABP7 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs762471805, COSV53362629; called by muse, mutect2, varscan2
- CACNA2D1 | c.2253T>A p.N751K (on ENST00000356253 / NM_001366867.1; = p.N739K on NM_000722.4) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV100667546; called by muse, mutect2, varscan2
- CAND2 | c.2681C>A p.P894H (on ENST00000456430 / NM_001162499.2; = p.P801H on NM_012298.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV99929936; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC9B | c.609del p.T204Rfs*44 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs772754432; called by mutect2, pindel, varscan2
- CD163L1 | c.1448G>A p.S483N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100550768; called by muse, mutect2, varscan2
- CDH11 | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.859); catalogued as COSV51764385, COSV51779360; called by muse, mutect2, varscan2
- CEP76 | c.1628T>G p.L543R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100043036; called by muse, mutect2, varscan2
- CHAT | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562560467, COSV100340238, COSV60330420; called by muse, varscan2
- CHL1 | c.613T>G p.F205V | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as COSV99850814, COSV99852570; called by muse, mutect2, varscan2
- COL7A1 | c.5982C>T p.G1994= | Splice Region (SNP) | VAF 23/48 reads (48%) | catalogued as COSV100097895, COSV60390620; called by muse, mutect2, varscan2
- CTNND2 | c.478T>C p.S160P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100481576; called by muse, mutect2, varscan2
- CXCL8 | c.*5del | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs201169323; called by mutect2, pindel, varscan2
- DBH | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748341921, COSV99708156; called by muse, mutect2, varscan2
- DCDC1 | c.3533C>T p.A1178V (on ENST00000597505 / NM_001367979.1; = p.A285V on NM_020869.3) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV100338863; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs766714372; called by mutect2, varscan2
- DLG4 | c.878G>A p.R293H (on ENST00000399506 / NM_001321075.3; = p.R336H on NM_001365.4) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.13); catalogued as rs749422436, COSV100264062; called by muse, mutect2, varscan2
- DMXL2 | c.5017A>G p.M1673V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs764505709, COSV99198749; called by muse, mutect2, varscan2
- DNAH1 | c.9239G>A p.R3080H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1179586168, COSV101327262; called by muse, mutect2, varscan2
- DYNC1I2 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.751); catalogued as rs1319542307, COSV99783869; called by muse, mutect2, varscan2
- EIF2AK4 | c.3621A>C p.K1207N | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99775471; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.089); catalogued as rs755900593, COSV99212827; called by muse, mutect2, varscan2
- EXOC7 | c.1267C>T p.R423* (on ENST00000335146 / NM_001145297.4; = p.R341* on NM_015219.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV58743451; called by muse, mutect2, varscan2
- FAF1 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.158); catalogued as COSV100876319; called by muse, mutect2, varscan2
- FBXL18 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs1435100280, COSV101154665; called by muse, mutect2
- FBXW8 | c.865G>A p.V289I (on ENST00000309909; = p.V327I on NM_012174.1) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.476); catalogued as rs755328748, COSV99998059; called by muse, mutect2, varscan2
- FGFR2 | c.1184T>A p.V395D | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV60650052; called by muse, mutect2, varscan2
- FHDC1 | c.2876G>T p.R959L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV52597301, COSV99471760; called by muse, mutect2, varscan2
- FRMPD2 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs748676341, COSV59714786, COSV59719823; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs763679060; called by mutect2, varscan2
- GPR37L1 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747799937, COSV66162006; called by muse, mutect2, varscan2
- GRHL3 | c.413C>G p.A138G (on ENST00000350501 / NM_198174.3; = p.A143G on NM_021180.3) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99359764; called by muse, mutect2, varscan2
- GRID1 | c.2462C>A p.A821D | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100026906; called by muse, mutect2, varscan2
- GRIK1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs142436130; called by muse, mutect2, varscan2
- GRK3 | c.1492-2A>G p.X498_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100152075; called by muse, mutect2, varscan2
- HEATR5B | c.2000C>T p.A667V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.121); catalogued as COSV99250369; called by muse, mutect2, varscan2
- HERC2 | c.10543A>G p.K3515E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV55330098, COSV99877329; called by muse, mutect2, varscan2
- HUS1B | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.165); catalogued as COSV100034297; called by muse, mutect2
- HUWE1 | c.13046C>T p.A4349V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.969); catalogued as COSV99474601; called by muse, mutect2
- IGF2R | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100808314; called by muse, mutect2, varscan2
- IGHE | c.913del p.H305Tfs*42 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | catalogued as rs1567136303; called by mutect2, pindel, varscan2
- IMPDH1 | c.469G>A p.V157I (on ENST00000470772 / NM_001142573.2; = p.V243I on NM_000883.4) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as rs779330002, COSV58316807; ClinVar: uncertain significance; called by muse, mutect2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs780982673; called by mutect2, varscan2
- ITPR2 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as COSV101190227; called by muse, mutect2, varscan2
- JADE3 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99510412; called by muse, mutect2, varscan2
- KCNH2 | c.1774C>A p.Q592K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100061277; called by muse, mutect2, varscan2
- KDM6B | c.1537del p.R513Afs*69 | Frame Shift Del (DEL) | VAF 13/26 reads (50%) | catalogued as rs747555402; called by mutect2, varscan2
- KDR | c.2417T>C p.M806T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99818854; called by muse, mutect2, varscan2
- KIF1A | c.4676G>A p.R1559Q (on ENST00000320389 / NM_001379639.1; = p.R1551Q on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs376658420; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KIF27 | c.3936del p.S1313Vfs*5 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as rs775622981; called by mutect2, pindel, varscan2
- KLF8 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1433525053, COSV63847297; called by muse, mutect2, varscan2
- KLHL42 | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67146209; called by muse, mutect2, varscan2
- KRTAP4-3 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs373753201; called by muse, mutect2, varscan2
- L3MBTL2 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV99346217; called by muse, mutect2, varscan2
- LIMK1 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100283501; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LRRC31 | c.1541A>G p.Q514R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1301180617, COSV99247164; called by muse, mutect2, varscan2
- LRRK2 | c.4900T>A p.F1634I | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV100111317; called by muse, mutect2, varscan2
- MBD3 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1252272706, COSV99337112; called by muse, mutect2, varscan2
- MDN1 | c.4117G>A p.A1373T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs776451057, COSV65524337; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | catalogued as rs780635289; called by mutect2, varscan2
- MUC13 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs764729299, COSV100222521; called by muse, mutect2, varscan2
- MYO10 | c.4130C>T p.T1377I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as rs781330078, COSV99946440; called by mutect2, varscan2
- MYO7A | c.1623del p.K542Rfs*80 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | catalogued as COSV68685202; called by mutect2, pindel, varscan2
- NAV3 | c.2132+8dup p.X711_splice | Splice Site (INS) | VAF 15/38 reads (39%) | catalogued as rs762130643; called by mutect2, varscan2
- NCAN | c.1509del p.M504Wfs*14 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as rs1166841736; called by mutect2, pindel, varscan2
- NFASC | c.2489G>A p.R830H (on ENST00000339876 / NM_001378329.1; = p.R933H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs762878608, COSV100366059; called by muse, mutect2, varscan2
- NOL6 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs901888326, COSV99955282; called by mutect2, varscan2
- NOTCH3 | c.3314del p.G1105Afs*167 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | catalogued as COSV54635564; called by mutect2, pindel, varscan2
- NRCAM | c.508C>A p.P170T (on ENST00000379028 / NM_001371124.1; = p.P164T on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100695682; called by muse, mutect2
- NSD1 | c.4999G>A p.A1667T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV61783262; called by muse, mutect2, varscan2
- NSDHL | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100938695; called by muse, mutect2, varscan2
- NSMAF | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as COSV99233133; called by muse, mutect2
- NXF3 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1480550067, COSV101222097; called by muse, mutect2
- OAS2 | c.370C>A p.L124I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100660341; called by muse, mutect2, varscan2
- OBSCN | c.7924G>A p.V2642I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.306); catalogued as COSV99485223; called by muse, mutect2, varscan2
- OR51G1 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111446872; called by muse, mutect2, varscan2
- OR8D1 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs781737847, COSV100766684; called by muse, mutect2, varscan2
- OTOF | c.5405C>T p.A1802V (on ENST00000272371 / NM_194248.3; = p.A1035V on NM_004802.4) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs144562626, COSV55506398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- P2RY8 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs751492615, COSV101184211; called by muse, mutect2, varscan2
- PACSIN3 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV100096679; called by muse, mutect2, varscan2
- PAPLN | c.2495C>A p.P832H (on ENST00000554301; = p.P805H on NM_173462.4) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV99390563; called by muse, mutect2, varscan2
- PARS2 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs140625560, COSV64883383; called by muse, mutect2, varscan2
- PCDHB12 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.846); catalogued as rs1554287044, COSV99507948; called by muse, mutect2, varscan2
- PCDHGB7 | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs747723647, COSV99548522; called by muse, mutect2, varscan2
- PCNX3 | c.5562dup p.V1855Rfs*7 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as rs763360634; called by mutect2, varscan2
- PDP1 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99893020; called by muse, mutect2, varscan2
- PKHD1L1 | c.6851G>A p.R2284Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756942445, COSV101005302, COSV65747020; called by muse, mutect2, varscan2
- PLA2G5 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV100908278, COSV100908281; called by muse, mutect2, varscan2
- PLEKHG2 | c.2471A>G p.Y824C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as COSV99218290; called by muse, mutect2, varscan2
- PLK1 | c.611A>G p.D204G | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs758709314, COSV100267528; called by muse, mutect2
- PLXNA4 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as rs765631133, COSV58142086; called by muse, mutect2, varscan2
- PNPLA5 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs1293399631, COSV99336794; called by muse, mutect2, varscan2
- POLR1A | c.4856G>A p.R1619Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs537491902, COSV55694213; called by muse, mutect2, varscan2
- PPP2R1A | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100436524; called by muse, mutect2, varscan2
- PRKACG | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55255646; called by muse, mutect2, varscan2
- PRKAR2A | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs147886817, COSV55551102; called by muse, mutect2, varscan2
- PRPS1L1 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs1345972445, COSV101552958; called by muse, mutect2, varscan2
- PSKH2 | c.640del p.S214Vfs*6 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs773860870, COSV52613193; called by mutect2, pindel, varscan2
- PTDSS1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61264202, COSV61265816; called by muse, mutect2, varscan2
- RAB36 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs765726662, COSV99321292; called by muse, mutect2, varscan2
- RASSF2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs754308859, COSV65082426; called by muse, mutect2, varscan2
- RDX | c.135del p.F45Lfs*6 | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | catalogued as COSV58192499; called by mutect2, pindel, varscan2
- RGN | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.233); catalogued as rs376108151, COSV60275614; called by muse, varscan2
- RNF111 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV62084267, COSV62087885; called by muse, mutect2, varscan2
- RNF31 | c.3205C>A p.R1069S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100138297, COSV60704046; called by muse, mutect2, varscan2
- SCN1A | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.932); catalogued as COSV100322469; called by muse, mutect2, varscan2
- SEPTIN12 | c.1024del p.R342Gfs*? | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | catalogued as rs757340930; called by mutect2, pindel, varscan2
- SIM1 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.001); catalogued as rs1021298872, COSV53488888; called by muse, mutect2, varscan2
- SINHCAF | c.218del p.N73Tfs*6 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs771414532; called by mutect2, varscan2
- SLC12A9 | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV99308280; called by muse, mutect2, varscan2
- SLC17A5 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV100867173; called by muse, mutect2, varscan2
- SLC22A4 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99569618; called by muse, mutect2
- SLC24A3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs376513919; called by muse, mutect2, varscan2
- SMYD4 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs368250516; called by muse, mutect2, varscan2
- SPATA46 | c.173G>T p.S58I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.413); catalogued as COSV100723662; called by muse, mutect2, varscan2
- ST8SIA2 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | PolyPhen probably damaging (0.977); catalogued as rs777052792, COSV51570496; called by muse, mutect2, varscan2
- SYNJ1 | c.3638G>A p.R1213H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); catalogued as rs776889207, COSV100449720; called by muse, mutect2
- SZT2 | c.7535A>G p.E2512G (on ENST00000634258 / NM_001365999.1; = p.E2455G on NM_015284.4) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100987708; called by muse, mutect2, varscan2
- TBC1D20 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100830635; called by muse, mutect2, varscan2
- TBK1 | c.1895C>T p.S632L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as rs1297925261, COSV59153284; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs758822980; called by mutect2, varscan2
- TDRD1 | c.2132G>A p.G711D | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs774487353, COSV99315295; called by muse, mutect2, varscan2
- TET3 | c.3404G>A p.G1135D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101328155, COSV69643485; called by muse, mutect2, varscan2
- TRAF7 | c.45del p.S17Afs*111 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | catalogued as rs753146456, COSV100399881; called by pindel, varscan2
- TRAV8-4 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.168); catalogued as rs756157958; called by muse, mutect2, varscan2
- TRIB3 | c.410del p.F137Sfs*73 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as COSV53931266; called by mutect2, varscan2
- UBN2 | c.759A>C p.E253D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99944559; called by muse, mutect2, varscan2
- UPF3B | c.451G>T p.V151F | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV99352410; called by muse, mutect2, varscan2
- UTP11 | c.436+2T>C p.X146_splice | Splice Site (SNP) | VAF 23/97 reads (24%) | catalogued as COSV100885006; called by muse, mutect2, varscan2
- VCAN | c.3673C>T p.P1225S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99427563; called by muse, mutect2
- VPS37A | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100246688; called by muse, mutect2, varscan2
- VWA8 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs773647628, COSV99864544, COSV99865377; called by muse, mutect2, varscan2
- WDR59 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs747440239, COSV50940903; called by muse, mutect2, varscan2
- WDR6 | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100556750; called by muse, mutect2, varscan2
- YDJC | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV99489024; called by muse, mutect2, varscan2
- ZFAT | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs373592555; called by muse, mutect2, varscan2
- ZIK1 | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV56736869; called by muse, mutect2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF563 | c.847T>C p.C283R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756372264, COSV99536826; called by muse, mutect2, varscan2
- ZNF709 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV67195938; called by muse, mutect2, varscan2
- ZNF829 | c.630dup p.P211Tfs*3 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | catalogued as rs752311498; called by mutect2, pindel, varscan2
- AFF2 | c.1041+5_1041+8del p.X347_splice | Splice Site (DEL) | VAF 44/156 reads (28%) | called by pindel, varscan2
- ARID1A | c.2751del p.N917Kfs*2 | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | called by mutect2, pindel, varscan2
- ATAT1 | c.899del p.P300Hfs*31 (on ENST00000376485; = p.P300Hfs*65 on NM_024909.4) | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | called by mutect2, pindel, varscan2
- CC2D1A | c.2346del p.R783Dfs*4 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by mutect2, pindel, varscan2
- CDC42EP1 | c.20del p.G7Afs*7 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- CFAP65 | c.1946del p.P649Rfs*5 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- CTCF | c.663del p.D222Mfs*28 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
- DISP2 | c.4104del p.P1369Qfs*87 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.960del p.P321Qfs*48 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel, varscan2
- EEA1 | c.1138_1140del p.E380del | In Frame Del (DEL) | VAF 6/58 reads (10%) | called by pindel, varscan2
- EPHA8 | c.1802del p.P601Rfs*82 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | called by mutect2, varscan2
- GBF1 | c.4659del p.C1554Afs*13 (on ENST00000369983 / NM_001377137.1; = p.C1553Afs*13 on NM_004193.3) | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- IARS1 | c.1801del p.M601* | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- LINGO3 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- NPR1 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2
- NUP214 | c.4582dup p.Q1528Pfs*8 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- PCGF2 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PDS5B | c.3658del p.T1220Rfs*10 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1059dup p.T354Dfs*10 (on ENST00000521381 / NM_181523.3; = p.T84Dfs*10 on NM_181504.4) | Frame Shift Ins (INS) | VAF 22/82 reads (27%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1408_1425+28del p.X470_splice (on ENST00000521381 / NM_181523.3; = p.X200_splice on NM_181504.4) | Splice Site (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- SHISA2 | c.525del p.S176Rfs*38 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- SP1 | c.1940dup p.L647Ffs*26 (on ENST00000327443 / NM_138473.3; = p.L640Ffs*26 on NM_003109.1) | Frame Shift Ins (INS) | VAF 4/50 reads (8%) | called by mutect2, pindel
- STON1 | c.1240_1242del p.E414del | In Frame Del (DEL) | VAF 9/21 reads (43%) | called by mutect2, pindel, varscan2
- TFAP2B | c.219del p.Y74Tfs*22 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- TRAM1 | c.35del p.P12Qfs*3 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | called by mutect2, pindel, varscan2
- TRIOBP | c.4547dup p.E1517* | Frame Shift Ins (INS) | VAF 42/138 reads (30%) | called by mutect2, varscan2
- USP24 | c.2661del p.T888Lfs*2 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- VDAC3 | c.699_702del p.S234Lfs*3 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- ZEB1 | c.1880dup p.W628Vfs*3 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- ZNF324 | c.415del p.V139Cfs*3 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- ZRSR2 | c.294del p.K98Nfs*10 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- AGMAT | c.609G>A p.A203= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs772056977, COSV101011816; called by muse, mutect2, varscan2
- ANKRD11 | c.4869G>A p.K1623= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs763457374, COSV99970818; called by muse, varscan2
- BFSP2 | c.285C>T p.T95= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs748115575, COSV100183992; ClinVar: benign; called by muse, mutect2, varscan2
- BMS1 | c.2925C>T p.H975= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV100996848; called by muse, mutect2
- CCDC73 | c.2337T>C p.L779= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV100068437; called by muse, mutect2, varscan2
- CLDN17 | c.387G>A p.T129= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs750659084, COSV99729457; called by muse, mutect2, varscan2
- DCHS1 | c.9456C>T p.A3152= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs750572199, COSV100197813; called by muse, mutect2, varscan2
- DCHS1 | c.483C>T p.R161= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1202416855, COSV100202681; called by muse, mutect2, varscan2
- DGKB | c.240T>C p.T80= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs1204007522, COSV51808166, COSV99343965; called by muse, mutect2, varscan2
- ELF1 | c.228T>C p.D76= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs767886505, COSV53499361; called by mutect2, varscan2
- ERN1 | c.948G>A p.L316= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV70505519; called by muse, mutect2, varscan2
- FAM193A | c.600C>T p.P200= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs748428684, COSV100219651; called by muse, mutect2, varscan2
- FZD2 | c.546C>T p.G182= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100190863; called by muse, mutect2, varscan2
- GMPS | c.1584C>T p.Y528= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs763386864, COSV55811898; called by muse, mutect2, varscan2
- HSD17B13 | c.366G>A p.G122= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100143361; called by muse, mutect2, varscan2
- KCND1 | c.1206G>A p.L402= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99502180; called by muse, mutect2, varscan2
- KCNN2 | c.474C>T p.G158= (on ENST00000264773; = p.G370= on NM_021614.4) | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99300880; called by muse, mutect2, varscan2
- KIF24 | c.1242C>T p.R414= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100799410; called by muse, mutect2, varscan2
- LAMA4 | c.3462C>T p.D1154= (on ENST00000230538 / NM_001105206.3; = p.D1147= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100039642, COSV57905413; called by muse, mutect2, varscan2
- LRG1 | c.912C>T p.D304= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100015207; called by muse, mutect2, varscan2
- LZTS1 | c.1729T>C p.L577= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs748832068, COSV56117903; called by muse, mutect2, varscan2
- MAPK9 | c.321T>C p.V107= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100558712; called by muse, mutect2
- MEGF10 | c.243A>G p.R81= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV99175820; called by muse, mutect2, varscan2
- MTPAP | c.1716C>A p.T572= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99554356; called by muse, mutect2
- MTUS2 | c.1443G>A p.T481= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs201515125; called by muse, mutect2, varscan2
- MUC5B | c.2595G>A p.K865= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV101500861; called by muse, mutect2, varscan2
- NKPD1 | c.1479G>A p.V493= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100521761; called by muse, mutect2, varscan2
- OPN1LW | c.618C>T p.D206= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs1459231886, COSV100885073; called by muse, mutect2, varscan2
- OR5D14 | c.618C>T p.T206= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV59455610; called by muse, mutect2, varscan2
- PACS2 | c.2289C>T p.D763= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs782639272, COSV100331046; called by muse, mutect2, varscan2
- PCDHA4 | c.1902G>A p.T634= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV100793181, COSV100793358; called by muse, mutect2, varscan2
- PCDHB2 | c.2232C>T p.T744= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99165429; called by muse, mutect2, varscan2
- PCDHGB5 | c.1687C>T p.L563= | Silent (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- PEX11B | c.465G>A p.R155= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100995061; called by muse, mutect2, varscan2
- PLEKHG4B | c.1296C>T p.A432= (on ENST00000283426; = p.A788= on NM_052909.5) | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs541524107, COSV99359799; called by muse, mutect2, varscan2
- PLXNA1 | c.3774G>A p.L1258= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs747993454, COSV99304258; called by muse, mutect2
- PRR11 | c.108T>A p.P36= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV51874852; called by muse, mutect2, varscan2
- PTPRE | c.90C>T p.N30= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs144835853; called by muse, mutect2, varscan2
- RCOR3 | c.1356A>G p.P452= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as rs1158762669, COSV100879725; called by muse, mutect2
- RGS6 | c.264C>T p.I88= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs151307395, COSV59593822; called by muse, mutect2, varscan2
- SNX31 | c.216T>C p.A72= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV100310586; called by muse, mutect2, varscan2
- SPTBN1 | c.348G>C p.V116= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100443542; called by muse, mutect2, varscan2
- STAB1 | c.4750C>A p.R1584= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100402376, COSV58733753; called by muse, mutect2, varscan2
- SUCLA2 | c.237A>G p.S79= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV101074991; called by muse, mutect2, varscan2
- SYNCRIP | c.1440A>G p.G480= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100784355; called by muse, mutect2, varscan2
- TECPR1 | c.1506G>A p.S502= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs778175378, COSV101130717; called by muse, mutect2, varscan2
- TMCC1 | c.1107C>A p.P369= (on ENST00000393238 / NM_001349268.2; = p.P45= on NM_015008.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100261361; called by muse, mutect2, varscan2
- TNS3 | c.3066C>T p.F1022= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs762256329, COSV60794579; called by muse, mutect2, varscan2
- TPO | c.2271G>A p.E757= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1240867637, COSV100222351; called by muse, mutect2, varscan2
- TRERF1 | c.3090G>A p.L1030= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1209879881, COSV100551869; called by muse, mutect2, varscan2
- TTN | c.53247C>T p.L17749= (on ENST00000591111; = p.L10325= on NM_003319.4) | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs754108889, COSV100597103, COSV60264715; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP6NL | c.1980T>C p.P660= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV99510208; called by muse, mutect2, varscan2
- VCPIP1 | c.1869C>T p.Y623= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs770871845, COSV60048027; called by muse, mutect2, varscan2
- VWA7 | c.2070G>C p.T690= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs980962009, COSV100991997; called by muse, mutect2, varscan2
- ZC3H7A | c.666G>A p.P222= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs762637256, COSV63271704; called by muse, mutect2, varscan2
- ZNF618 | c.225C>T p.I75= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1261923855, COSV99931185; called by muse, mutect2, varscan2
- CPLANE1 | c.*4603G>A | 3'UTR (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99951965; called by muse, mutect2, varscan2
- SLC9A3R1 | c.*2C>T | 3'UTR (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99380337; called by muse, mutect2, varscan2
- TPI1 | c.*259C>T | 3'UTR (SNP) | VAF 18/57 reads (32%) | catalogued as rs1037955406, COSV51290545; called by muse, mutect2, varscan2
- TRAC | c.*456del | 3'UTR (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- TRIM61 | c.526-2136T>A | Intron (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
